Surgical pathology report (de-identified scan), TCGA case TCGA-B0-4814, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-4814-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: KIDNEY, RIGHT, RADICAL NEPHRECTOMY -

- A. RENAL CELL CARCINOMA; CONVENTIONAL (CLEAR CELL) TYPE, 12.5 CM; MODERATELY DIFFERENTIATED, FURMAN NUCLEAR GRADE, 3 OF 4.
- B. TUMOR GROWTH PATTERN IS PREDOMINANTLY ACINAR.
- C. TUMOR FOCALLY EXTENDS BEYOND GEROTA'S FASCIA.
- D. TUMOR GROSS AND MICROSCOPICALLY INVOLVES RENAL VEIN RESECTION MARGIN.
- E. NON-NEOPLASTIC KIDNEY SHOWS FOCAL CHRONIC INTERSTITIAL NEPHRITIS.
- F. ADRENAL GLAND IS UNREMARKABLE.
- G. TNM PATHOLOGIC STAGE = pT4 NX M1.
- H. TNM HISTOLOGIC GRADE = G3.

PART 2: "HEPATIC TUMOR", EXCISION:

- A. METASTATIC CLEAR CELL CARCINOMA, MORPHOLOGICALLY CONSISTENT WITH A RENAL PRIMARY.
- B. EXTENSIVE TUMOR NECROSIS IS NOTED.

Source: NCI Genomic Data Commons file 33933071-2848-4757-8a75-e6b58d6a4da5 (TCGA-B0-4814.E0D0D90D-CE06-4DE2-B3D5-4A516C6CA0A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).